Somatic mutation profile of tumor specimen TCGA-PR-A5PG-01A (aliquot TCGA-PR-A5PG-01A-11D-A35D-08) from TCGA case TCGA-PR-A5PG, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, malignant; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 42.6 years (15,577 days).
Specimen TCGA-PR-A5PG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a6dfc840-27cf-4b85-a7a9-29b0a873563d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-PR-A5PG-10A (Blood Derived Normal), aliquot TCGA-PR-A5PG-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2ae5b7f6-e727-41ef-92e8-4295a448de8b

The open-access MAF lists 17 somatic variants for this specimen: 13 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 12, Silent 4, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 32/54 reads (59%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs104894228, CM060018, COSV54236651, COSV54236730, COSV54241641; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BPTF | c.8296G>A p.E2766K | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.13); catalogued as rs782100405; called by muse, mutect2, varscan2
- ITGA10 | c.2919G>A p.R973= | Splice Region (SNP) | VAF 17/43 reads (40%) | catalogued as COSV65196578; called by muse, mutect2, varscan2
- PCMTD2 | c.991C>T p.P331S | Missense Mutation (SNP) | VAF 54/140 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.537); catalogued as rs1428020201; called by muse, mutect2, varscan2
- TMCO4 | c.1019C>T p.A340V | Missense Mutation (SNP) | VAF 22/29 reads (76%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as rs751988022; called by muse, mutect2, varscan2
- TTC12 | c.904T>C p.S302P | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.36); catalogued as COSV59097285; called by muse, mutect2, varscan2
- CACHD1 | c.1861A>C p.T621P | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- F8 | c.2422G>A p.D808N | Missense Mutation (SNP) | VAF 69/167 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FAM53B | c.393G>C p.R131S | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- KCNB1 | c.1027A>G p.M343V | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- KRT3 | c.181G>A p.G61S | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- LONRF3 | c.1537G>T p.A513S (on ENST00000371628 / NM_001031855.3; = p.A472S on NM_024778.5) | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- RMDN1 | c.422T>C p.L141P | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CACNA1D | c.5589A>G p.Q1863= (on ENST00000350061 / NM_001128840.3; = p.Q1883= on NM_000720.4) | Silent (SNP) | VAF 31/67 reads (46%) | called by muse, mutect2, varscan2
- CDC27 | c.1462T>C p.L488= | Silent (SNP) | VAF 82/234 reads (35%) | called by muse, mutect2, varscan2
- MUC5B | c.12513C>A p.G4171= | Silent (SNP) | VAF 32/139 reads (23%) | called by muse, mutect2, varscan2
- SLC2A10 | c.966C>A p.P322= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as rs771950521; called by muse, mutect2, varscan2
